Somatic mutation profile of tumor specimen TCGA-13-1504-01A (aliquot TCGA-13-1504-01A-01W-0545-08) from TCGA case TCGA-13-1504, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 68.5 years (25,008 days).
Specimen TCGA-13-1504-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abf7afe8-2cb6-4871-bcbf-97e5816d6f22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1504-10A (Blood Derived Normal), aliquot TCGA-13-1504-10A-01W-0546-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef3c1b1f-aba1-47bf-9877-dd8402ba0054

The open-access MAF lists 47 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, In Frame Del 1, 5'UTR 1, Nonsense Mutation 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.752T>G p.I251S | Missense Mutation (SNP) | VAF 392/652 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs730882027, COSV52728902, COSV52741592, COSV52816233, COSV53108676; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.7579C>T p.R2527W (on ENST00000560601 / NM_001369268.1; = p.R2489W on NM_013227.3) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61366803; called by muse, mutect2, varscan2
- ADAMTSL1 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 124/1125 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV52821981; called by muse, mutect2, varscan2
- AMER3 | c.922A>T p.R308W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV58469034; called by muse, mutect2, varscan2
- CBWD1 | c.40C>G p.P14A | Missense Mutation (SNP) | VAF 59/435 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs1480028601, COSV58701871; called by muse, mutect2, varscan2
- DCAF4L2 | c.448G>C p.A150P | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.905); catalogued as COSV60477574, COSV60481308; called by muse, mutect2, varscan2
- DNAH8 | c.6893T>C p.F2298S | Missense Mutation (SNP) | VAF 88/368 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59471023; called by muse, mutect2, varscan2
- DYNC1H1 | c.8666T>A p.L2889* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV64140658; called by muse, varscan2
- FLNC | c.3464C>T p.P1155L | Missense Mutation (SNP) | VAF 27/273 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs769243979, COSV57961948; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLB1L2 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.049); catalogued as rs1202161431, COSV60280099; called by muse, mutect2, varscan2
- ING3 | c.809G>C p.R270T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); catalogued as COSV59951817; called by muse, mutect2, varscan2
- ITPKB | c.1827_1829del p.S611del | In Frame Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs762021610; called by pindel, varscan2
- KCNN2 | c.976G>A p.A326T (on ENST00000264773; = p.A538T on NM_021614.4) | Missense Mutation (SNP) | VAF 71/296 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1333683293, COSV53295207, COSV99299133; called by muse, mutect2, varscan2
- MAS1L | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV65809489; called by muse, mutect2, varscan2
- MAST4 | c.743C>T p.S248L (on ENST00000403625 / NM_001164664.2; = p.S59L on NM_015183.3) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV55136739; called by muse, mutect2, varscan2
- MED10 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs767344062, COSV55386622; called by muse, mutect2, varscan2
- MLLT3 | c.859A>G p.I287V | Missense Mutation (SNP) | VAF 144/582 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100581439; called by mutect2, varscan2
- NAB1 | c.1131C>A p.F377L | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100493120; called by muse, mutect2
- OPTN | c.1077A>C p.K359N | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV99537202; called by muse, mutect2
- OR7C1 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs373552926; called by muse, mutect2, varscan2
- PLP1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 201/791 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.761); catalogued as rs132630295, CM078425, CM1312266, COSV58277298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKAR2B | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 76/413 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55924125; called by muse, varscan2
- SF3A3 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 12/293 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.177); catalogued as COSV100885677; called by muse, mutect2
- SLC44A1 | c.476G>T p.C159F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV66026888; called by muse, mutect2, varscan2
- SRRM4 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.838); catalogued as rs532719039, COSV57423555; called by muse, mutect2, varscan2
- ST3GAL6 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 208/1445 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs1363757233, COSV54583898; called by muse, mutect2, varscan2
- SUPT6H | c.4344C>G p.I1448M | Missense Mutation (SNP) | VAF 151/438 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.135); catalogued as COSV100112681; called by muse, varscan2
- UNC5A | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs895075991, COSV56168970; called by muse, mutect2, varscan2
- WBP2NL | c.16A>T p.S6C | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV52173582; called by muse, mutect2, varscan2
- WDR90 | c.1474G>A p.G492S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.586); catalogued as rs766670247, COSV53473820; called by muse, mutect2
- WIPF2 | c.64-1G>A p.X22_splice | Splice Site (SNP) | VAF 29/166 reads (17%) | catalogued as COSV60275226; called by muse, mutect2, varscan2
- ZNF410 | c.1151G>C p.S384T | Missense Mutation (SNP) | VAF 50/652 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV100206549; called by muse, mutect2
- FRG2C | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 27/346 reads (8%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.954); called by muse, mutect2
- IGKC | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- AP5M1 | c.1320A>G p.T440= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV55106429; called by muse, mutect2
- CABIN1 | c.2167C>A p.R723= | Silent (SNP) | VAF 20/302 reads (7%) | catalogued as COSV99573813; called by muse, mutect2
- CHRD | c.2157G>A p.A719= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs763065776, COSV52611337; called by muse, mutect2, varscan2
- FOXC1 | c.441C>T p.G147= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs376255999; called by muse, mutect2, varscan2
- GRIN2B | c.4125G>A p.K1375= | Silent (SNP) | VAF 30/480 reads (6%) | catalogued as COSV101663140; called by muse, mutect2
- H4C6 | c.294G>A p.L98= | Silent (SNP) | VAF 26/212 reads (12%) | catalogued as COSV100897503; called by muse, mutect2, varscan2
- IQCC | c.468C>T p.S156= | Silent (SNP) | VAF 117/314 reads (37%) | catalogued as rs1350488506, COSV52210529; called by muse, mutect2, varscan2
- PAPOLB | c.150C>T p.F50= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs367608195; called by muse, mutect2, varscan2
- RAP1GAP | c.231C>A p.T77= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs776966810, COSV51576338; called by muse, mutect2, varscan2
- STAB2 | c.4788C>T p.R1596= | Silent (SNP) | VAF 87/481 reads (18%) | catalogued as rs751986200, COSV66339454; called by muse, mutect2, varscan2
- ZFHX4 | c.7125C>T p.N2375= | Silent (SNP) | VAF 91/483 reads (19%) | catalogued as rs1457303675, COSV51443681, COSV51476529; called by muse, mutect2, varscan2
- AMACR | c.-2C>T | 5'UTR (SNP) | VAF 10/60 reads (17%) | catalogued as rs748324238, COSV100163207; called by muse, mutect2, varscan2
- C20orf197 | n.491T>C | RNA (SNP) | VAF 31/295 reads (11%) | catalogued as rs948289243; called by muse, mutect2, varscan2
